Somatic mutation profile of tumor specimen TCGA-FS-A1ZS-06A (aliquot TCGA-FS-A1ZS-06A-12D-A197-08) from TCGA case TCGA-FS-A1ZS, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 62.5 years (22,844 days).
Specimen TCGA-FS-A1ZS-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 336c4215-9979-45dc-aaac-19b9354247f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A1ZS-10A (Blood Derived Normal), aliquot TCGA-FS-A1ZS-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ce688c0-d0c8-4e97-846a-a047c1c319ca

The open-access MAF lists 333 somatic variants for this specimen: 196 protein-altering or splice-affecting, 132 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 178, Silent 132, Nonsense Mutation 10, Splice Site 5, Intron 3, Frame Shift Del 2, Splice Region 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/100 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- IKZF1 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 11/17 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.212); catalogued as rs759124417, COSV58782650, COSV58783750; called by muse, mutect2, varscan2
- NCR1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 84/131 reads (64%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as COSV52555848; called by muse, mutect2, varscan2
- A2ML1 | c.1591G>A p.D531N | Missense Mutation (SNP) | VAF 63/115 reads (55%) | SIFT tolerated (0.3); PolyPhen benign (0.296); catalogued as COSV55287561; called by muse, mutect2, varscan2
- ABHD2 | c.413G>A p.S138N | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.18); catalogued as COSV61773200; called by muse, mutect2, varscan2
- AC100868.1 | c.1439C>T p.S480F | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51839810, COSV99225154; called by muse, mutect2
- ACOX3 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT tolerated (0.31); PolyPhen benign (0.05); catalogued as COSV62711274; called by muse, mutect2, varscan2
- ACVR1B | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 58/111 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57775360, COSV57775773; called by muse, mutect2, varscan2
- ADAM7 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51536751; called by muse, mutect2, varscan2
- ADAMTS20 | c.2816G>T p.G939V | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV67129016; called by muse, mutect2, varscan2
- ADAMTS5 | c.1886G>A p.R629H | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755967040, COSV53177017; called by muse, mutect2, varscan2
- ADGRV1 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67980725; called by muse, mutect2, varscan2
- AKAP3 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.478); catalogued as COSV57415026; called by muse, mutect2, varscan2
- ALG10B | c.1416G>A p.M472I | Missense Mutation (SNP) | VAF 70/109 reads (64%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.53); catalogued as rs777456744, COSV58142687; called by muse, mutect2, varscan2
- ALMS1 | c.8654G>C p.R2885P | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.148); catalogued as COSV100042067, COSV52505265; called by muse, mutect2, varscan2
- ANK2 | c.11717G>A p.R3906Q | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs770001324, COSV52151566; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD30A | c.450G>C p.E150D (on ENST00000611781; = p.E94D on NM_052997.2) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV64606510; called by muse, mutect2, varscan2
- ANLN | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.557); catalogued as rs1032999052, COSV56074600; called by muse, mutect2, varscan2
- ARF5 | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1297082014, COSV99133941; called by muse, mutect2, varscan2
- ARHGAP26 | c.1904T>C p.L635P | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.445); catalogued as COSV50825652; called by muse, mutect2, varscan2
- ASB3 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55074437; called by muse, varscan2
- ATAD2 | c.2204T>A p.L735* | Nonsense Mutation (SNP) | VAF 18/73 reads (25%) | catalogued as COSV54878729; called by muse, mutect2, varscan2
- ATP12A | c.1924A>C p.I642L | Missense Mutation (SNP) | VAF 86/149 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as COSV54513745; called by muse, mutect2, varscan2
- ATP7B | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 42/58 reads (72%) | SIFT deleterious (0.05); PolyPhen benign (0.142); catalogued as COSV54436376, COSV54441682; called by muse, mutect2, varscan2
- ATP9A | c.1250C>T p.S417L | Missense Mutation (SNP) | VAF 62/145 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV58764421; called by muse, mutect2, varscan2
- AVEN | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs372785565, COSV100145281, COSV60733085; called by muse, mutect2, varscan2
- B4GALNT2 | c.276C>A p.F92L | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV55925277, COSV55928319; called by muse, mutect2, varscan2
- BAZ2B | c.3578T>C p.L1193P | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54275107; called by muse, mutect2, varscan2
- BBS9 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.052); catalogued as rs899716022, COSV54157337; called by muse, mutect2, varscan2
- BCO1 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.271); catalogued as rs1277923022, COSV50728550; called by muse, mutect2, varscan2
- BMS1 | c.2155A>G p.N719D | Missense Mutation (SNP) | VAF 85/102 reads (83%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV65733177; called by muse, mutect2, varscan2
- C12orf50 | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 48/73 reads (66%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV53894092; called by muse, mutect2, varscan2
- CACNA1E | c.4289G>A p.G1430E | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62385721; called by muse, mutect2, varscan2
- CAD | c.2812C>T p.L938F | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV53024726; called by muse, mutect2, varscan2
- CAMSAP1 | c.3034G>A p.G1012R | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as COSV56720264; called by muse, mutect2
- CDH8 | c.547+1G>A p.X183_splice | Splice Site (SNP) | VAF 18/45 reads (40%) | catalogued as COSV54855017; called by muse, mutect2, varscan2
- CEP97 | c.1963C>T p.P655S | Missense Mutation (SNP) | VAF 63/74 reads (85%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs774648568, COSV59123375; called by muse, mutect2, varscan2
- CGB5 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV100032131; called by muse, mutect2, varscan2
- CHERP | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.262); catalogued as rs568640108, COSV52223137; called by muse, mutect2, varscan2
- CHRM3 | c.1076C>T p.S359F | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.515); catalogued as COSV55083917; called by muse, mutect2
- CISH | c.107C>T p.P36L (on ENST00000348721 / NM_145071.4; = p.P53L on NM_013324.6) | Missense Mutation (SNP) | VAF 27/33 reads (82%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV62294670; called by muse, mutect2, varscan2
- CKAP2L | c.2155G>A p.E719K | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.651); catalogued as COSV100198771; called by muse, mutect2, varscan2
- COL11A1 | c.4867T>C p.W1623R | Missense Mutation (SNP) | VAF 38/46 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV62176160; called by muse, mutect2, varscan2
- COL12A1 | c.2180G>A p.R727Q | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as rs775023310, COSV59391815; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL7A1 | c.3941G>A p.G1314E | Missense Mutation (SNP) | VAF 50/61 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60392865; called by muse, mutect2, varscan2
- COL7A1 | c.2236G>C p.D746H | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV60392868; called by muse, mutect2
- CSMD2 | c.7265C>T p.P2422L | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53890496; called by muse, mutect2, varscan2
- CYP2C19 | c.1310G>A p.G437E | Missense Mutation (SNP) | VAF 59/81 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64907175; called by muse, mutect2, varscan2
- DBF4 | c.511C>T p.H171Y | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.888); catalogued as rs778253160, COSV55996254; called by muse, mutect2, varscan2
- DBR1 | c.454C>T p.H152Y | Missense Mutation (SNP) | VAF 206/247 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53429157; called by muse, mutect2, varscan2
- DDO | c.511G>A p.E171K (on ENST00000368924 / NM_001368172.1; = p.E112K on NM_004032.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as rs267600760, COSV64469830; called by muse, mutect2, varscan2
- DDR1 | c.1816C>T p.P606S (on ENST00000324771; = p.P569S on NM_001954.4) | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs1405305923, COSV61319266; called by muse, mutect2, varscan2
- DGKZ | c.3026A>G p.D1009G (on ENST00000454345 / NM_001105540.2; = p.D821G on NM_003646.4) | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV58986159; called by muse, mutect2, varscan2
- DNAH12 | c.267G>A p.M89I | Missense Mutation (SNP) | VAF 31/35 reads (89%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1455805018, COSV60856053; called by muse, mutect2, varscan2
- DPP8 | c.1909T>G p.S637A (on ENST00000341861 / NM_001320875.2; = p.S621A on NM_017743.6) | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.366); catalogued as COSV55676945; called by muse, mutect2, varscan2
- DSCAM | c.4777C>T p.L1593F | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.299); catalogued as COSV68023138; called by muse, mutect2, varscan2
- DSCAM | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs1183479997, COSV68021948; called by muse, mutect2, varscan2
- EDRF1 | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 50/56 reads (89%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV61762831; called by muse, mutect2, varscan2
- ELOVL4 | c.288+1G>A p.X96_splice | Splice Site (SNP) | VAF 6/20 reads (30%) | catalogued as COSV63953519; called by muse, mutect2
- EXD2 | c.1553A>T p.Q518L (on ENST00000312994 / NM_001193362.1; = p.Q393L on NM_018199.3) | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs780087461, COSV57278766; called by muse, mutect2, varscan2
- F8 | c.5012G>A p.R1671H | Missense Mutation (SNP) | VAF 54/62 reads (87%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs782166477, CM082643, COSV64270712; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM47C | c.433C>T p.L145F | Missense Mutation (SNP) | VAF 37/49 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV63724796; called by muse, mutect2, varscan2
- FBXO48 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200307344, COSV58143365, COSV58143970; called by muse, mutect2, varscan2
- FCER1A | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 41/59 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs751533005, COSV63666565; called by muse, mutect2, varscan2
- FCRL4 | c.1360+1G>T p.X454_splice | Splice Site (SNP) | VAF 25/43 reads (58%) | catalogued as COSV99620429; called by muse, mutect2, varscan2
- FCRL4 | c.1360G>A p.V454I | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.221); catalogued as COSV99620432; called by muse, mutect2, varscan2
- FFAR4 | c.828C>G p.F276L | Missense Mutation (SNP) | VAF 100/112 reads (89%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV101012306, COSV65159747; called by muse, mutect2, varscan2
- FMNL3 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs372559306; called by muse, mutect2, varscan2
- FOXR1 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs370698214, COSV57651604; called by muse, mutect2, varscan2
- FPR1 | c.131A>G p.N44S | Missense Mutation (SNP) | VAF 41/55 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59051325; called by muse, mutect2, varscan2
- GALNT5 | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as rs144689586, COSV52036497; called by muse, mutect2, varscan2
- GCOM1 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as rs756208577, COSV51088533; called by muse, mutect2, varscan2
- GPAM | c.1149A>C p.R383S | Missense Mutation (SNP) | VAF 63/74 reads (85%) | SIFT tolerated (0.17); PolyPhen benign (0.169); catalogued as COSV62080523, COSV62083291; called by muse, mutect2, varscan2
- GPER1 | c.445A>T p.T149S | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52471093, COSV99867385; called by muse, mutect2, varscan2
- GPER1 | c.446C>A p.T149N | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99867388; called by muse, mutect2, varscan2
- GPR158 | c.2366G>A p.R789K | Missense Mutation (SNP) | VAF 70/81 reads (86%) | SIFT tolerated (0.51); PolyPhen benign (0.011); catalogued as COSV66266996, COSV66270584; called by muse, mutect2, varscan2
- GPR20 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1197461926, COSV66684068; called by muse, mutect2, varscan2
- GPRIN3 | c.850G>A p.V284M | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV60884391; called by muse, mutect2, varscan2
- GPSM3 | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 123/258 reads (48%) | catalogued as COSV66679500; called by muse, mutect2, varscan2
- GSS | c.23T>C p.L8P | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV53811958; called by muse, mutect2, varscan2
- GXYLT2 | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 92/124 reads (74%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV67473686; called by muse, mutect2, varscan2
- HACE1 | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs760591663, COSV53500114, COSV53505813; called by muse, mutect2, varscan2
- HSPB2 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.857); catalogued as COSV99909972; called by muse, mutect2, varscan2
- HYDIN | c.7538G>A p.R2513K | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.81); PolyPhen benign (0.038); catalogued as COSV59250556; called by muse, mutect2, varscan2
- IGF1R | c.3802G>A p.E1268K | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV51273139; called by muse, mutect2, varscan2
- INSYN2A | c.805G>A p.G269S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.85); PolyPhen benign (0.009); catalogued as COSV54733483; called by muse, mutect2
- KCNH1 | c.1835G>A p.G612E (on ENST00000271751 / NM_172362.3; = p.G585E on NM_002238.4) | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55073402; called by muse, mutect2, varscan2
- KMT2A | c.6370C>T p.R2124* | Nonsense Mutation (SNP) | VAF 38/115 reads (33%) | catalogued as CM1511940, COSV63283453; called by muse, mutect2, varscan2
- KMT2B | c.6257C>T p.S2086L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs1468457510, COSV55857463; called by muse, mutect2
- KPNA6 | c.1447C>T p.Q483* | Nonsense Mutation (SNP) | VAF 11/88 reads (13%) | catalogued as COSV65359616, COSV65361057; called by muse, mutect2, varscan2
- KRT20 | c.634G>A p.V212I | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as COSV51424270; called by muse, mutect2, varscan2
- L3MBTL1 | c.1121A>G p.N374S (on ENST00000418998 / NM_001377303.1; = p.N284S on NM_015478.7) | Missense Mutation (SNP) | VAF 73/160 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs999050460, COSV64228079; called by muse, mutect2, varscan2
- LEFTY2 | c.497+1G>A p.X166_splice | Splice Site (SNP) | VAF 11/21 reads (52%) | catalogued as rs1054502693, COSV64746556; called by muse, varscan2
- LGSN | c.1251C>G p.Y417* | Nonsense Mutation (SNP) | VAF 18/70 reads (26%) | catalogued as COSV65726513; called by muse, mutect2, varscan2
- LILRB1 | c.721C>T p.P241S (on ENST00000427581; = p.P205S on NM_006669.6) | Missense Mutation (SNP) | VAF 120/170 reads (71%) | SIFT deleterious (0.04); PolyPhen benign (0.337); catalogued as COSV61116765, COSV61118652; called by muse, mutect2, varscan2
- LPCAT2 | c.1568C>T p.S523F | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as rs1254155348, COSV50894585; called by muse, mutect2, varscan2
- MAGEC1 | c.2083C>T p.P695S | Missense Mutation (SNP) | VAF 47/56 reads (84%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.29); catalogued as rs1295614131, COSV53569766; called by muse, mutect2, varscan2
- MAP3K10 | c.1549C>T p.R517C | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV53421236; called by muse, mutect2
- MCF2 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 37/44 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58480380; called by muse, mutect2, varscan2
- MED17 | c.937C>T p.R313W | Missense Mutation (SNP) | VAF 65/121 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52599992; called by muse, mutect2, varscan2
- MPL | c.1799G>A p.G600E | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV65244392; called by muse, mutect2, varscan2
- MRGPRX1 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV57106347; called by muse, mutect2, varscan2
- MTUS2 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs373199820; called by muse, mutect2, varscan2
- MUC16 | c.34450G>A p.E11484K | Missense Mutation (SNP) | VAF 103/151 reads (68%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as COSV67453269; called by muse, mutect2, varscan2
- MYH11 | c.3136G>A p.E1046K | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV55546619, COSV55553518; called by muse, mutect2, varscan2
- NEBL | c.117G>A p.M39I | Missense Mutation (SNP) | VAF 127/157 reads (81%) | SIFT tolerated (0.11); PolyPhen benign (0.326); catalogued as COSV65799536; called by muse, mutect2, varscan2
- NUP98 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 74/136 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs769185645, COSV100263453; called by muse, mutect2, varscan2
- NUP98 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 76/137 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.357); catalogued as COSV61436660; called by muse, mutect2, varscan2
- OR10H2 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV59945601; called by muse, mutect2, varscan2
- OR4S2 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV56746238; called by muse, mutect2, varscan2
- OR51E2 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.188); catalogued as rs565364663, COSV67806631, COSV67806703, COSV67807925; called by muse, mutect2, varscan2
- OR52B2 | c.213G>A p.M71I | Missense Mutation (SNP) | VAF 88/181 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs775492942, COSV73209270; called by muse, mutect2, varscan2
- OR5B3 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV58676582; called by muse, mutect2, varscan2
- OR5D14 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748386955, COSV59455727, COSV59457599; called by muse, mutect2, varscan2
- OR6C1 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.009); catalogued as rs867442232, COSV65572609; called by muse, mutect2, varscan2
- OR6C74 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.767); catalogued as rs1222522277, COSV59605933; called by muse, mutect2, varscan2
- OR8B3 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 92/190 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV63541442; called by muse, mutect2, varscan2
- OR9Q2 | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 46/133 reads (35%) | catalogued as rs757826869, COSV61111553; called by muse, mutect2, varscan2
- PAPLN | c.2965A>C p.K989Q (on ENST00000554301; = p.K962Q on NM_173462.4) | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT tolerated (0.99); PolyPhen benign (0.018); catalogued as COSV53714942; called by muse, mutect2, varscan2
- PCDHA11 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 64/125 reads (51%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV56475009; called by muse, mutect2, varscan2
- PCDHB5 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV50648318, COSV99169681; called by muse, mutect2, varscan2
- PDCL | c.470A>T p.Q157L | Missense Mutation (SNP) | VAF 49/70 reads (70%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV99414229; called by muse, mutect2, varscan2
- PDCL | c.469C>A p.Q157K | Missense Mutation (SNP) | VAF 51/72 reads (71%) | SIFT tolerated (0.65); PolyPhen benign (0.03); catalogued as COSV99035415, COSV99414231; called by muse, mutect2, varscan2
- PDE1B | c.706C>T p.H236Y | Missense Mutation (SNP) | VAF 157/263 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1184660451, COSV54490804; called by muse, mutect2, varscan2
- PEAR1 | c.96G>A p.W32* | Nonsense Mutation (SNP) | VAF 59/102 reads (58%) | catalogued as COSV52771903; called by muse, varscan2
- PLCB4 | c.2627G>A p.G876E | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.996); catalogued as rs866533934, COSV53796419; called by muse, mutect2, varscan2
- PLEKHM2 | c.2095A>G p.K699E | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.024); catalogued as COSV65395545; called by muse, mutect2, varscan2
- PPP1R16B | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV55375355; called by muse, mutect2, varscan2
- PSG4 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 171/252 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as COSV54934205; called by muse, mutect2, varscan2
- PTPRT | c.2486G>A p.G829E | Missense Mutation (SNP) | VAF 240/627 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100630407; called by muse, mutect2, varscan2
- PWWP3B | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 21/21 reads (100%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.765); catalogued as COSV61798734, COSV61801985; called by muse, mutect2, varscan2
- RBAK | c.1529C>T p.P510L | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs752330581, COSV62331625; called by muse, varscan2
- RBM48 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.276); catalogued as COSV50395414; called by muse, varscan2
- RFX6 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 56/97 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.037); catalogued as rs767918169, COSV60583999; called by muse, mutect2, varscan2
- RGS18 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs988087391, COSV100817909, COSV66507541; called by muse, mutect2, varscan2
- RGS6 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.588); catalogued as rs1205242935, COSV59568643, COSV59603952; called by muse, mutect2
- RMND5A | c.305G>C p.S102T | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.93); PolyPhen benign (0.015); catalogued as COSV52153067; called by muse, mutect2, varscan2
- RNF19B | c.1903C>A p.P635T | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.037); catalogued as rs370533666, COSV52387051, COSV52387293; called by muse, mutect2, varscan2
- RP1 | c.3352C>T p.H1118Y | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV55111043; called by muse, mutect2, varscan2
- RPUSD4 | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs747071058, COSV53598891; called by muse, mutect2, varscan2
- RXFP1 | c.658G>A p.G220R | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57047853, COSV57048559; called by muse, mutect2, varscan2
- SACS | c.7523G>A p.R2508K | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.13); catalogued as COSV66536556; called by muse, mutect2, varscan2
- SDK1 | c.3503C>T p.T1168I | Missense Mutation (SNP) | VAF 83/162 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67360445; called by muse, mutect2, varscan2
- SEMA6D | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV100317588; called by muse, mutect2, varscan2
- SERPINA1 | c.1228G>A p.G410R | Missense Mutation (SNP) | VAF 86/144 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63345420; called by muse, mutect2, varscan2
- SETD1A | c.1511C>T p.S504F | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV52685894; called by muse, mutect2, varscan2
- SF3B2 | c.635A>G p.Q212R | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.029); catalogued as COSV59427375; called by muse, mutect2, varscan2
- SHOC2 | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 62/77 reads (81%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV54620564; called by muse, mutect2, varscan2
- SLC22A25 | c.25C>T p.Q9* | Nonsense Mutation (SNP) | VAF 20/69 reads (29%) | catalogued as COSV60594710, COSV60599880; called by muse, mutect2, varscan2
- SLC36A2 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58862504; called by muse, mutect2, varscan2
- SLC5A12 | c.199G>T p.V67F | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99745504; called by muse, mutect2, varscan2
- SLC6A3 | c.1646G>A p.G549E | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0.014); catalogued as COSV54362564; called by muse, mutect2, varscan2
- SLC7A2 | c.212C>T p.S71F (on ENST00000494857 / NM_001370338.1; = p.S111F on NM_003046.6) | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV50248963; called by muse, mutect2, varscan2
- SLC9A2 | c.1312C>T p.R438* | Nonsense Mutation (SNP) | VAF 57/110 reads (52%) | catalogued as rs1361191978, COSV52129888; called by muse, mutect2, varscan2
- SLFN11 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57697724; called by muse, mutect2, varscan2
- SNAP91 | c.2105G>A p.G702E | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV52118253; called by muse, mutect2, varscan2
- SNCAIP | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV54404853, COSV99751093; called by muse, mutect2, varscan2
- SSX3 | c.122A>G p.K41R | Missense Mutation (SNP) | VAF 65/74 reads (88%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.985); catalogued as rs113403735, COSV53643399; called by muse, mutect2, varscan2
- STK24 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 59/88 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64822595; called by muse, mutect2, varscan2
- SVEP1 | c.5378G>A p.G1793E | Missense Mutation (SNP) | VAF 22/24 reads (92%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs749945364, COSV52836896; called by muse, mutect2, varscan2
- SVEP1 | c.2515G>A p.D839N | Missense Mutation (SNP) | VAF 79/91 reads (87%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV57031782; called by muse, mutect2, varscan2
- SYNPO2 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 42/58 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV61107997; called by muse, mutect2, varscan2
- TAS2R8 | c.701T>A p.I234N | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV53688231; called by muse, mutect2, varscan2
- TAZ | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54795987; called by muse, varscan2
- TMC1 | c.1979C>T p.P660L | Missense Mutation (SNP) | VAF 138/173 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM161330, COSV52769815; called by muse, mutect2, varscan2
- TMEM132B | c.1279G>C p.D427H | Missense Mutation (SNP) | VAF 10/258 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV54748051; called by muse, mutect2
- TMEM41B | c.176C>T p.S59F | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV55154722; called by muse, mutect2, varscan2
- TOE1 | c.237-1G>A p.X79_splice | Splice Site (SNP) | VAF 22/34 reads (65%) | catalogued as COSV100517707; called by muse, mutect2, varscan2
- TOE1 | c.237G>A p.Q79= | Splice Region (SNP) | VAF 22/33 reads (67%) | catalogued as COSV100517708; called by muse, mutect2, varscan2
- TRPC6 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as rs761950641, COSV60251991; called by muse, mutect2, varscan2
- TSHZ3 | c.2594C>T p.P865L | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as rs1469546750, COSV99552685; called by muse, mutect2, varscan2
- TSHZ3 | c.2593C>T p.P865S | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.521); catalogued as COSV53685631, COSV99552172; called by muse, mutect2, varscan2
- TTN | c.99904C>T p.R33302* (on ENST00000591111; = p.R25878* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 31/78 reads (40%) | catalogued as rs1202115268, COSV59942116; called by muse, mutect2
- TTN | c.62339G>A p.G20780E (on ENST00000591111; = p.G13356E on NM_003319.4) | Missense Mutation (SNP) | VAF 47/129 reads (36%) | PolyPhen probably damaging (1); catalogued as COSV100631007, COSV59942139; called by muse, mutect2, varscan2
- TTN | c.56822C>T p.T18941I (on ENST00000591111; = p.T11517I on NM_003319.4) | Missense Mutation (SNP) | VAF 25/55 reads (45%) | PolyPhen possibly damaging (0.79); catalogued as COSV59942160; called by muse, mutect2, varscan2
- U2SURP | c.2644C>T p.L882F | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67530335; called by muse, mutect2, varscan2
- UCP1 | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV53767520; called by muse, mutect2, varscan2
- UGT2B10 | c.1565G>A p.G522E | Missense Mutation (SNP) | VAF 47/78 reads (60%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs767442442, COSV55319359; called by muse, mutect2, varscan2
- UGT2B4 | c.1022G>A p.G341E | Missense Mutation (SNP) | VAF 62/116 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs191191560; called by muse, mutect2, varscan2
- UGT3A1 | c.1160G>A p.G387E | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.81); catalogued as COSV57096535; called by muse, mutect2, varscan2
- UNC79 | c.3193G>A p.E1065K (on ENST00000393151 / NM_001346218.2; = p.E888K on NM_020818.5) | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56379107, COSV56391667; called by muse, mutect2, varscan2
- UPP2 | c.482C>T p.T161M | Missense Mutation (SNP) | VAF 84/235 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.919); catalogued as rs781145130, COSV50046348; called by muse, mutect2, varscan2
- USP21 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 35/55 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV57087288, COSV99237862; called by muse, mutect2, varscan2
- USP21 | c.1321C>T p.R441W | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs767763815, COSV57087302; called by muse, mutect2, varscan2
- VPS13B | c.3491A>G p.Y1164C | Missense Mutation (SNP) | VAF 63/239 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62136424; called by muse, mutect2, varscan2
- VPS54 | c.992A>G p.Q331R | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.212); catalogued as COSV55438830; called by muse, mutect2, varscan2
- ZNF131 | c.1489C>A p.Q497K (on ENST00000509156 / NM_001330707.2; = p.Q463K on NM_003432.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.169); catalogued as COSV61001577; called by muse, mutect2
- ZNF266 | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 61/98 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV100749443; called by muse, mutect2, varscan2
- ZNF266 | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 61/97 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs1482098458, COSV100749444; called by muse, mutect2, varscan2
- ZNF646 | c.3092C>T p.P1031L | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV54923397; called by muse, mutect2, varscan2
- ZNF804A | c.1616G>A p.G539E | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV56440249; called by muse, mutect2, varscan2
- ZNF831 | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1463687867, COSV64038430; called by muse, mutect2, varscan2
- C20orf27 | c.327_329delinsAA p.A110Sfs*13 (on ENST00000379772 / NM_001258429.2; = p.A135Sfs*13 on NM_001039140.3) | Frame Shift Del (DEL) | VAF 21/77 reads (27%) | called by pindel, varscan2*
- IGHV6-1 | c.308C>T p.S103F | Missense Mutation (SNP) | VAF 103/149 reads (69%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- SALL3 | c.3064del p.Q1022Sfs*4 | Frame Shift Del (DEL) | VAF 33/71 reads (46%) | called by mutect2, pindel, varscan2
- TRBJ2-2 | c.40C>A p.L14M | Missense Mutation (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2, varscan2
- AADACL3 | c.1215G>A p.K405= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV100206744, COSV60198421; called by muse, mutect2, varscan2
- ACBD4 | c.702C>T p.F234= (on ENST00000376955 / NM_001378111.1; = p.R238* on NM_024722.4) | Silent (SNP) | VAF 58/82 reads (71%) | catalogued as rs772269471, COSV58851119; called by muse, mutect2, varscan2
- ACBD6 | c.345C>T p.I115= | Silent (SNP) | VAF 34/48 reads (71%) | catalogued as rs767195068, COSV62572212; called by muse, mutect2, varscan2
- ADAMTS18 | c.3045A>G p.E1015= | Silent (SNP) | VAF 40/108 reads (37%) | catalogued as COSV51401157; called by muse, mutect2, varscan2
- AGBL1 | c.3294C>T p.F1098= | Silent (SNP) | VAF 79/237 reads (33%) | catalogued as COSV66852612; called by muse, mutect2, varscan2
- AHNAK2 | c.8307C>T p.A2769= | Silent (SNP) | VAF 131/210 reads (62%) | catalogued as rs1359179140, COSV60910640; called by muse, mutect2, varscan2
- ANGPTL1 | c.1221G>A p.G407= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as COSV52365766; called by muse, mutect2, varscan2
- ANKRD55 | c.1101G>A p.R367= | Silent (SNP) | VAF 94/226 reads (42%) | catalogued as COSV61944984, COSV61950718; called by muse, mutect2, varscan2
- ANO5 | c.2208A>T p.G736= | Silent (SNP) | VAF 61/121 reads (50%) | catalogued as COSV61083263; called by muse, mutect2, varscan2
- ARF5 | c.222T>A p.I74= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as COSV99133937; called by muse, mutect2, varscan2
- ARHGAP29 | c.2565C>G p.P855= | Silent (SNP) | VAF 61/79 reads (77%) | catalogued as COSV53109655; called by muse, mutect2, varscan2
- C2orf49 | c.528C>T p.D176= | Silent (SNP) | VAF 28/54 reads (52%) | catalogued as COSV51527272; called by muse, mutect2, varscan2
- C5orf46 | c.55C>T p.L19= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV59153666; called by muse, mutect2, varscan2
- CCDC191 | c.801G>A p.V267= | Silent (SNP) | VAF 126/156 reads (81%) | catalogued as COSV55670836; called by muse, mutect2, varscan2
- CDH15 | c.147C>T p.I49= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as COSV57022654; called by muse, mutect2, varscan2
- CFAP47 | c.2685G>A p.G895= | Silent (SNP) | VAF 53/68 reads (78%) | catalogued as COSV52882001; called by muse, mutect2, varscan2
- CFHR3 | c.423C>T p.I141= | Silent (SNP) | VAF 29/59 reads (49%) | catalogued as COSV66401764; called by muse, mutect2, varscan2
- CKAP2L | c.2154A>G p.L718= | Silent (SNP) | VAF 51/143 reads (36%) | catalogued as COSV100198773; called by muse, mutect2, varscan2
- CLEC4C | c.606G>A p.Q202= | Silent (SNP) | VAF 34/57 reads (60%) | catalogued as COSV63582393; called by muse, mutect2, varscan2
- CLSTN2 | c.438C>T p.V146= | Silent (SNP) | VAF 55/60 reads (92%) | catalogued as COSV71719103; called by muse, mutect2, varscan2
- COL3A1 | c.360T>C p.N120= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as COSV58584222; called by muse, mutect2, varscan2
- COL5A3 | c.4221G>A p.L1407= | Silent (SNP) | VAF 107/154 reads (69%) | catalogued as COSV53407917; called by muse, mutect2, varscan2
- CRB1 | c.675T>C p.I225= | Silent (SNP) | VAF 48/195 reads (25%) | catalogued as COSV66337815; called by muse, mutect2, varscan2
- CSMD1 | c.9924C>T p.F3308= (on ENST00000520002; = p.F3307= on NM_033225.6) | Silent (SNP) | VAF 38/83 reads (46%) | catalogued as rs753525110, COSV59294648; called by muse, mutect2, varscan2
- CSMD2 | c.1893C>T p.F631= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as COSV53886957; called by muse, mutect2, varscan2
- CSNK1A1L | c.288C>T p.S96= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as COSV65789467; called by muse, mutect2, varscan2
- CSPG5 | c.822C>T p.D274= | Silent (SNP) | VAF 12/13 reads (92%) | catalogued as COSV53130368; called by muse, mutect2
- CYP2A7 | c.1152C>T p.F384= | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as COSV52499164, COSV52507331; called by muse, mutect2, varscan2
- DACT1 | c.2304G>A p.G768= | Silent (SNP) | VAF 57/94 reads (61%) | catalogued as rs770570404, COSV60019887; called by muse, mutect2, varscan2
- DAPK2 | c.60G>A p.E20= | Silent (SNP) | VAF 34/107 reads (32%) | catalogued as rs964571011, COSV56044294; called by muse, mutect2, varscan2
- DBH | c.153C>T p.I51= | Silent (SNP) | VAF 19/27 reads (70%) | catalogued as COSV55040104; called by muse, mutect2, varscan2
- DDR1 | c.1815C>T p.F605= (on ENST00000324771; = p.F568= on NM_001954.4) | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as COSV61321355; called by mutect2, varscan2
- DLST | c.832C>T p.L278= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV53165733; called by muse, mutect2, varscan2
- DNAH8 | c.1041G>A p.G347= | Silent (SNP) | VAF 19/29 reads (66%) | catalogued as rs766446337, COSV59432365; called by muse, mutect2, varscan2
- DSCAM | c.4602C>T p.I1534= | Silent (SNP) | VAF 32/59 reads (54%) | catalogued as COSV68023144; called by muse, mutect2, varscan2
- DSCAM | c.2940C>T p.D980= | Silent (SNP) | VAF 42/67 reads (63%) | catalogued as rs1347862161, COSV68023150; called by muse, mutect2, varscan2
- EYA1 | c.492C>T p.L164= | Silent (SNP) | VAF 67/189 reads (35%) | catalogued as COSV58159046; called by muse, mutect2, varscan2
- EZH2 | c.1221C>T p.S407= (on ENST00000460911 / NM_001203247.2; = p.S412= on NM_004456.5) | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as COSV57448838; called by muse, mutect2, varscan2
- FAAH2 | c.765G>A p.Q255= | Silent (SNP) | VAF 46/54 reads (85%) | catalogued as COSV66506171; called by muse, mutect2, varscan2
- FASN | c.5316C>T p.F1772= | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as rs138763798; ClinVar: likely benign; called by muse, varscan2
- FAT1 | c.3849C>T p.P1283= | Silent (SNP) | VAF 158/258 reads (61%) | catalogued as COSV71672852; called by muse, mutect2, varscan2
- FIBIN | c.252C>T p.F84= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs774804006, COSV59412607; called by muse, mutect2, varscan2
- FMNL3 | c.156C>T p.A52= | Silent (SNP) | VAF 18/87 reads (21%) | catalogued as COSV99526966; called by muse, mutect2, varscan2
- FSHR | c.1158C>T p.I386= | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as COSV58619860; called by muse, mutect2, varscan2
- FTMT | c.78C>T p.F26= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV58419997; called by muse, mutect2, varscan2
- GABRB2 | c.1389G>A p.K463= (on ENST00000274547; = p.K425= on NM_000813.3) | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV50905005; called by muse, mutect2, varscan2
- GID4 | c.552C>T p.H184= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV52008366; called by muse, mutect2, varscan2
- GLRA1 | c.408C>T p.F136= | Silent (SNP) | VAF 51/92 reads (55%) | catalogued as COSV51007438, COSV51008702; called by muse, mutect2, varscan2
- GLYATL1 | c.339G>A p.G113= (on ENST00000317391 / NM_001354699.1; = p.G144= on NM_080661.4) | Silent (SNP) | VAF 36/98 reads (37%) | catalogued as rs776658060, COSV55606855, COSV55606875, COSV55607788; called by muse, mutect2, varscan2
- GPRC5B | c.381C>T p.F127= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV56025668; called by muse, mutect2, varscan2
- GRID2 | c.777C>T p.I259= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as COSV56184384; called by muse, mutect2, varscan2
- GRM3 | c.2310C>T p.F770= | Silent (SNP) | VAF 54/86 reads (63%) | catalogued as COSV64468808, COSV64480208; called by muse, mutect2, varscan2
- HSPB2 | c.495C>T p.L165= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV99909971; called by muse, mutect2, varscan2
- IGHV4-28 | c.186G>A p.G62= | Silent (SNP) | VAF 23/163 reads (14%) | catalogued as rs782211529; called by muse, mutect2, varscan2
- IGSF22 | c.2073C>T p.A691= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV60031949; called by muse, mutect2, varscan2
- IL17A | c.186G>A p.R62= | Silent (SNP) | VAF 23/108 reads (21%) | catalogued as COSV60684115; called by muse, mutect2, varscan2
- INPPL1 | c.1212C>T p.F404= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs866410983, COSV53354156; called by muse, mutect2
- INTS1 | c.4503C>T p.L1501= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs375382080; called by muse, mutect2
- KIAA0930 | c.1054C>T p.L352= (on ENST00000336156 / NM_001009880.2; = p.L357= on NM_015264.2) | Silent (SNP) | VAF 22/116 reads (19%) | catalogued as rs367658177; called by muse, mutect2, varscan2
- KIAA0930 | c.1053C>T p.S351= (on ENST00000336156 / NM_001009880.2; = p.S356= on NM_015264.2) | Silent (SNP) | VAF 22/114 reads (19%) | catalogued as rs1427175630, COSV52665699; called by muse, mutect2, varscan2
- KMT2A | c.5124A>G p.L1708= | Silent (SNP) | VAF 38/73 reads (52%) | catalogued as rs556592051, COSV63283445; called by muse, mutect2, varscan2
- LAMA1 | c.129G>A p.E43= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs1449500168, COSV67533662; called by muse, mutect2
- LDB2 | c.165C>T p.A55= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as COSV58764827; called by muse, mutect2, varscan2
- LIX1 | c.210G>A p.V70= | Silent (SNP) | VAF 38/88 reads (43%) | catalogued as COSV57206452; called by muse, mutect2, varscan2
- LLGL1 | c.1395G>A p.V465= | Silent (SNP) | VAF 55/87 reads (63%) | catalogued as COSV57496766; called by muse, mutect2, varscan2
- LTN1 | c.1398C>T p.S466= | Silent (SNP) | VAF 40/129 reads (31%) | catalogued as COSV100798098, COSV63733277; called by muse, mutect2, varscan2
- MAT2A | c.912C>T p.S304= | Silent (SNP) | VAF 28/53 reads (53%) | catalogued as COSV52087414; called by muse, mutect2, varscan2
- MCPH1 | c.1440C>T p.T480= | Silent (SNP) | VAF 39/78 reads (50%) | catalogued as rs749070717, COSV60911414; called by muse, mutect2, varscan2
- MED12L | c.5925A>T p.A1975= | Silent (SNP) | VAF 113/120 reads (94%) | catalogued as COSV56372359; called by muse, mutect2, varscan2
- MOGS | c.2016C>T p.L672= | Silent (SNP) | VAF 42/111 reads (38%) | catalogued as rs753542237, COSV51968621; called by muse, mutect2, varscan2
- MUC16 | c.15621A>C p.T5207= | Silent (SNP) | VAF 42/255 reads (16%) | catalogued as COSV67453275; called by muse, mutect2, varscan2
- MUC17 | c.11967G>A p.K3989= | Silent (SNP) | VAF 32/155 reads (21%) | catalogued as COSV60282425, COSV60283089; called by muse, mutect2, varscan2
- MYH1 | c.3009C>T p.L1003= | Silent (SNP) | VAF 31/206 reads (15%) | catalogued as rs267604713, COSV56845238; called by muse, mutect2, varscan2
- MYRF | c.972G>A p.P324= (on ENST00000278836 / NM_001127392.3; = p.P315= on NM_013279.4) | Silent (SNP) | VAF 24/150 reads (16%) | catalogued as rs752770747, COSV53886932; called by muse, mutect2, varscan2
- NEUROD4 | c.291G>A p.R97= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as rs267603557, COSV54470963; called by muse, mutect2, varscan2
- NINL | c.3780C>T p.A1260= | Silent (SNP) | VAF 35/65 reads (54%) | catalogued as rs368328747; called by muse, mutect2, varscan2
- NPAP1 | c.2328C>T p.A776= | Silent (SNP) | VAF 70/185 reads (38%) | catalogued as rs761682423, COSV61504992, COSV61512003; called by muse, mutect2, varscan2
- NR2E1 | c.783C>T p.I261= | Silent (SNP) | VAF 45/70 reads (64%) | catalogued as COSV64561351, COSV64561680; called by muse, mutect2, varscan2
- OBSL1 | c.2976C>T p.Y992= | Silent (SNP) | VAF 44/106 reads (42%) | catalogued as COSV54704253; called by muse, mutect2, varscan2
- OPCML | c.897G>A p.T299= | Silent (SNP) | VAF 35/62 reads (56%) | catalogued as rs150470513, COSV59411049; called by muse, mutect2, varscan2
- OR10J5 | c.93C>T p.F31= | Silent (SNP) | VAF 43/74 reads (58%) | catalogued as rs748213019, COSV58384961; called by muse, mutect2, varscan2
- OR1M1 | c.411C>T p.S137= | Silent (SNP) | VAF 97/143 reads (68%) | catalogued as rs779190474, COSV70036596; called by muse, mutect2, varscan2
- OR51A7 | c.36C>T p.F12= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as rs867579601, COSV63788113; called by muse, mutect2, varscan2
- OR52K1 | c.330C>T p.S110= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as COSV56903255; called by muse, mutect2, varscan2
- OR56B4 | c.249C>T p.I83= | Silent (SNP) | VAF 34/71 reads (48%) | catalogued as COSV57204188; called by muse, mutect2, varscan2
- OR6C4 | c.85C>T p.L29= | Silent (SNP) | VAF 71/110 reads (65%) | catalogued as COSV67792825; called by muse, mutect2, varscan2
- OR7G3 | c.196C>T p.L66= | Silent (SNP) | VAF 76/120 reads (63%) | catalogued as COSV59639879, COSV59640076; called by muse, mutect2, varscan2
- PCDHAC2 | c.459C>T p.Y153= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as COSV53841134; called by muse, mutect2, varscan2
- PCDHB4 | c.2349G>A p.K783= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV52020679; called by muse, mutect2, varscan2
- PITPNM2 | c.834C>T p.D278= | Silent (SNP) | VAF 52/82 reads (63%) | catalogued as COSV54897639; called by muse, varscan2
- PLEKHG4 | c.469T>C p.L157= | Silent (SNP) | VAF 35/114 reads (31%) | catalogued as COSV64612040; called by muse, mutect2, varscan2
- POTEF | c.2460C>T p.T820= | Silent (SNP) | VAF 75/147 reads (51%) | catalogued as rs1392565667, COSV62540355; called by muse, mutect2, varscan2
- PPP1R3A | c.2880C>T p.I960= | Silent (SNP) | VAF 67/98 reads (68%) | catalogued as rs1438273502, COSV52878695; called by muse, mutect2, varscan2
- PRMT5 | c.1365C>T p.H455= | Silent (SNP) | VAF 44/245 reads (18%) | catalogued as COSV53545211; called by muse, mutect2, varscan2
- RBAK | c.1530C>T p.P510= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100806768; called by muse, varscan2
- RP1 | c.2172G>A p.G724= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as CD992277, COSV55112640; called by muse, mutect2, varscan2
- RYR1 | c.10404C>T p.S3468= | Silent (SNP) | VAF 124/156 reads (79%) | catalogued as COSV62092362; called by muse, mutect2
- SCARA5 | c.1437G>T p.V479= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV61571369, COSV61571725; called by muse, mutect2, varscan2
- SCN9A | c.5379G>A p.A1793= (on ENST00000303354; = p.A1782= on NM_002977.3) | Silent (SNP) | VAF 46/105 reads (44%) | catalogued as rs201875421; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- SEMA6D | c.87C>T p.P29= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as COSV60374317; called by muse, mutect2, varscan2
- SFTPB | c.531C>T p.V177= | Silent (SNP) | VAF 47/102 reads (46%) | catalogued as rs751001412, COSV60892872; called by muse, mutect2, varscan2
- SLC5A12 | c.198G>A p.T66= | Silent (SNP) | VAF 33/62 reads (53%) | catalogued as rs763774969, COSV54820740, COSV99745507; called by muse, mutect2, varscan2
- SLC8A3 | c.174C>T p.V58= | Silent (SNP) | VAF 27/44 reads (61%) | catalogued as COSV63519839; called by muse, mutect2, varscan2
- SLCO1B3 | c.552G>A p.G184= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV53934320; called by muse, mutect2, varscan2
- SLITRK1 | c.1701G>A p.K567= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs761823041, COSV65674734, COSV65676708; called by muse, mutect2
- SLITRK4 | c.1245G>A p.V415= | Silent (SNP) | VAF 57/65 reads (88%) | catalogued as COSV62022735; called by muse, mutect2, varscan2
- SNX27 | c.1065G>A p.L355= | Silent (SNP) | VAF 50/87 reads (57%) | catalogued as rs200042975, COSV64325866; called by muse, mutect2, varscan2
- STRIP2 | c.1185C>T p.D395= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV50803577; called by muse, mutect2, varscan2
- SWAP70 | c.1740G>A p.E580= | Silent (SNP) | VAF 46/85 reads (54%) | catalogued as COSV59662887; called by muse, mutect2, varscan2
- TAS2R38 | c.582C>A p.S194= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV71885155, COSV71885960; called by muse, mutect2, varscan2
- TAS2R60 | c.438C>T p.F146= | Silent (SNP) | VAF 35/191 reads (18%) | catalogued as rs1422538149, COSV60330136; called by muse, mutect2, varscan2
- TAS2R60 | c.948G>A p.G316= | Silent (SNP) | VAF 18/144 reads (13%) | catalogued as COSV60330388; called by muse, mutect2
- TEX11 | c.1782G>A p.P594= (on ENST00000344304; = p.P579= on NM_031276.3) | Silent (SNP) | VAF 37/45 reads (82%) | catalogued as rs1169045883, COSV60227866; called by muse, mutect2, varscan2
- THEMIS | c.126T>C p.C42= | Silent (SNP) | VAF 15/20 reads (75%) | catalogued as COSV64069814; called by muse, mutect2, varscan2
- TNP2 | c.366C>T p.I122= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as COSV57129242; called by muse, mutect2, varscan2
- TRBV4-1 | c.213G>A p.E71= | Silent (SNP) | VAF 109/170 reads (64%) | catalogued as rs1476055172; called by muse, mutect2, varscan2
- TRIM7 | c.999G>C p.R333= | Silent (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- TRIM7 | c.951G>A p.K317= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV51240981; called by muse, mutect2, varscan2
- TRPV4 | c.678C>T p.F226= | Silent (SNP) | VAF 25/39 reads (64%) | catalogued as COSV55681106; called by muse, mutect2, varscan2
- TTN | c.46326C>T p.V15442= (on ENST00000591111; = p.V8018= on NM_003319.4) | Silent (SNP) | VAF 83/200 reads (42%) | catalogued as COSV59942185; called by muse, mutect2, varscan2
- TTN | c.12234G>A p.L4078= (on ENST00000591111; = p.L4032= on NM_003319.4) | Silent (SNP) | VAF 35/71 reads (49%) | catalogued as COSV100629341; called by muse, mutect2, varscan2
- TTN | c.8406G>A p.K2802= (on ENST00000591111; = p.K2756= on NM_003319.4) | Silent (SNP) | VAF 37/105 reads (35%) | catalogued as COSV59942220; called by muse, mutect2, varscan2
- UGT1A6 | c.1542G>A p.R514= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as COSV59384513; called by muse, mutect2, varscan2
- UTRN | c.2559C>A p.P853= | Silent (SNP) | VAF 25/44 reads (57%) | catalogued as COSV62330235; called by muse, mutect2, varscan2
- WDTC1 | c.651C>T p.I217= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV60087521; called by muse, mutect2
- YBX3 | c.660G>A p.R220= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV54387183; called by muse, mutect2, varscan2
- ZCCHC14 | c.1068G>A p.E356= (on ENST00000268616; = p.E493= on NM_015144.3) | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV51884735; called by muse, varscan2
- ZCCHC3 | c.1101G>A p.R367= | Silent (SNP) | VAF 55/99 reads (56%) | catalogued as rs761857446, COSV66642991; called by muse, mutect2, varscan2
- ZFHX3 | c.3420C>T p.T1140= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV51712271; called by muse, mutect2, varscan2
- ZFPL1 | c.417G>A p.E139= | Silent (SNP) | VAF 38/98 reads (39%) | catalogued as rs1283329567, COSV51868872; called by muse, mutect2, varscan2
- ZNF300 | c.1188G>A p.L396= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as COSV51032523; called by muse, mutect2, varscan2
- ZNF713 | c.444G>A p.K148= (on ENST00000633730 / NM_001366796.2; = p.K161= on NM_182633.3) | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV70056509; called by muse, mutect2, varscan2
- AL133467.6 | n.96C>T | RNA (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- ERCC6 | c.1397+7545T>C | Intron (SNP) | VAF 58/66 reads (88%) | catalogued as COSV100875856; called by muse, mutect2, varscan2
- INSL6 | c.*1C>T | 3'UTR (SNP) | VAF 22/27 reads (81%) | catalogued as COSV101068529; called by mutect2, varscan2
- MROH8 | c.370+2543C>T | Intron (SNP) | VAF 18/47 reads (38%) | catalogued as COSV54118359; called by muse, mutect2, varscan2
- SYTL2 | c.1459+2605T>G | Intron (SNP) | VAF 19/54 reads (35%) | catalogued as COSV100314965; called by muse, mutect2, varscan2
